Gene-level copy-number profile of tumor specimen HCM-SANG-0530-C15-08A-01D-A80T-32 from HCMI case HCM-SANG-0530-C15, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Esophagus, NOS; Tumor grade: G2.
Specimen HCM-SANG-0530-C15-08A-01D-A80T-32: Sample type: Post neo-adjuvant therapy; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 9eeff2c7-40b7-4fcf-9fd8-cf9c7ab289b4.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-SANG-0530-C15-10A-01D-A80T-32 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,713 have no estimate.
https://portal.gdc.cancer.gov/files/3e56553f-7a82-4f78-9d5c-9ce69bc74fca

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 56; copy number 1: 18,902; copy number 2: 36,982; copy number 3: 2,347; copy number 4: 337; copy number 5: 7; copy number 6: 6; copy number 7: 4; copy number 8: 238; copy number 13: 31.

Homozygous deletions (total copy number 0; autosomes only): 56 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:37,891,084–38,287,491, 5 genes: TBC1D1, PTTG2, PSME2P4, MRPS33P2, AC098680.1.
- chr4:90,682,996–90,683,123, 1 gene (within-gene range 0–2): AC093729.1.
- chr8:39,451,045–39,522,852, 1 gene: ADAM3A.
- chr9:61,581,813–61,662,690, 4 genes: AL935212.3, FAM242D, Y_RNA, AL935212.1.
- chr14:18,692,032–18,712,643, 4 genes: RPL22P20, CR383656.4, CR383656.2, NF1P10.
- chr14:49,927,571–50,105,043, 1 gene (within-gene range 0–2): LINC01588.
- chr14:50,050,368–50,087,083, 4 genes: PDLIM1P1, AL117692.1, RN7SKP193, Y_RNA.
- chr16:78,495,926–78,553,296, 4 genes (within-gene range 0–1): AC046158.1, AC046158.4, AC046158.2, AC046158.3.
- chr20:14,933,843–15,022,958, 3 genes (within-gene range 0–2): AL138808.1, RNU6-1159P, RNU6-115P.
- chr21:7,744,962–8,701,562, 29 genes: SMIM11B, FAM243B, SMIM34B, KCNE1B, CU633980.1, FP671120.5, FP671120.4, MIR6724-1, FP671120.1, MIR3648-1, FP671120.2, FP671120.6, RNA5-8SN2, MIR6724-2, FP671120.3, FP671120.7, 5_8S_rRNA, FP236383.3, MIR6724-3, FP236383.1, FP236383.4, RNA5-8SN3, MIR6724-4, FP236383.2, FP236383.5, RNA5-8SN1, RPSAP68, CR381572.2, CR381572.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 286 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:6,952,625–7,104,482, 4 genes, copy number 5: AC079804.3, MIR3683, AC092104.1, Y_RNA.
- chr13:73,112,915–73,227,260, 3 genes, copy number 5: RNU6-66P, RNU4-10P, RNY1P8.
- chr18:6,729,716–6,937,020, 6 genes, copy number 6 (within-gene range 3–6): ARHGAP28, AP005210.2, AP005210.1, LINC00668, SCML2P1, RNU6-916P.
- chr19:29,811,991–37,304,395, 264 genes, copy number 8–13 (broad region; genes not listed).
- chr20:53,255,979–53,668,758, 9 genes, copy number 7–13 (within-gene range 2–13): AL109930.1, AL354993.1, PPIAP10, AL354993.2, Y_RNA, AL157838.1, ZNF217, AC005808.1, RNU7-14P.

Autosomal genes at a single copy (total copy number 1): 16,046. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
